Somatic mutation profile of tumor specimen TARGET-10-PATLNZ-09A (aliquot TARGET-10-PATLNZ-09A-01D) from TARGET case TARGET-10-PATLNZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.9 years (3,601 days).
Specimen TARGET-10-PATLNZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82df48d4-fecf-4223-899b-46105be1c1d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATLNZ-10A (Blood Derived Normal), aliquot TARGET-10-PATLNZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e746fcc1-e5f6-48c7-a230-62d5972f5c07

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'Flank 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/78 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZBTB7A | c.1272G>T p.K424N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59326106; called by muse, mutect2, varscan2
- DPEP2 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1567440531, COSV52054170; called by muse, mutect2, varscan2
- DTL | c.1457T>C p.V486A | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV65342043; called by muse, mutect2, varscan2
- ENPP3 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV62953645; called by muse, mutect2, varscan2
- ITSN1 | c.3971C>T p.P1324L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1410877412, COSV67156995; called by muse, mutect2, varscan2
- MGAM2 | c.4274C>T p.P1425L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs563508674; called by muse, mutect2, varscan2
- MYH4 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55115315, COSV99700870; called by muse, mutect2, varscan2
- NLRP12 | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs143739468; called by muse, mutect2, varscan2
- PTEN | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 34/65 reads (52%) | catalogued as rs1554825174, COSV64292017; called by muse, mutect2, varscan2
- TAF1 | c.1724C>T p.A575V (on ENST00000373790 / NM_138923.4; = p.A596V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0.277); catalogued as COSV52110207; called by muse, mutect2, varscan2
- IGHV3-23 | c.351_352insAAAGGCC | In Frame Ins (INS) | VAF 19/92 reads (21%) | called by mutect2, pindel*, varscan2*
- TRBV7-7 | c.311delinsCCC p.R104Pfs*13 | Frame Shift Ins (INS) | VAF 29/44 reads (66%) | called by pindel, varscan2*
- ERICH3 | c.1335C>T p.I445= | Silent (SNP) | VAF 52/187 reads (28%) | catalogued as COSV58618204; called by muse, mutect2, varscan2
- MTHFSD | c.682-42C>T | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as rs371031373; called by muse, mutect2, varscan2
- TRAJ50 | chr14:22492850 ins TACA | 3'Flank (INS) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
